Gene-level copy-number profile of tumor specimen TCGA-BR-4255-01A from TCGA case TCGA-BR-4255, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 76.4 years (27,893 days).
Specimen TCGA-BR-4255-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.620b4219-46a3-4bb9-a0f3-cb556d0625d2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-4255-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f2e3068d-cfa6-4922-8387-030dea8266f7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 981; copy number 2: 19,851; copy number 3: 29,149; copy number 4: 7,798; copy number 5: 1,606; copy number 6: 4; copy number 7: 64; copy number 8: 221; copy number 11: 3; copy number 14: 10; copy number 20: 42; copy number 24: 13; copy number 27: 7; copy number 29: 6; copy number 33: 11; copy number 44: 24; copy number 51: 18; copy number 53: 4; copy number 60: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-4255-01A-01D-1130-01): tumor purity 0.21, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 427 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:94,278,680–103,152,325, 285 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:2,648,075–2,926,689, 4 genes, copy number 27 (within-gene range 3–27): AC246817.2, AC246817.1, AC115485.1, AC023296.1.
- chr8:6,708,642–6,930,473, 10 genes, copy number 29–53: AGPAT5, MIR4659A, MIR4659B, AF233439.2, XKR5, GS1-24F4.2, DEFB1, RPL23AP96, DEFA6, AF233439.1.
- chr8:7,414,855–7,896,716, 42 genes, copy number 20: DEFB4B, HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, AC134684.11, PRR23D1, AC134684.12, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1, AC134684.10, AC084121.2, AC084121.3, AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, AC084121.4, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A.
- chr8:9,002,147–9,436,205, 15 genes, copy number 33–60 (within-gene range 3–60): ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P.
- chr8:10,474,565–10,730,511, 12 genes, copy number 24: LINCR-0001, PRSS52P, RNU6-729P, AC104964.1, PRSS51, AC104964.3, PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7.
- chr8:10,729,314–10,772,910, 1 gene, copy number 24 (within-gene range 3–24): AC105001.1.
- chr8:11,331,012–11,950,753, 24 genes, copy number 11–51: SLC35G5, TDH, AF131216.3, FAM167A-AS1, RN7SL293P, RNU6-1084P, FAM167A, AF131216.5, BLK, AC022239.1, LINC00208, AC022239.2, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, AC107918.5, AC107918.6.
- chr12:25,195,216–26,833,194, 34 genes, copy number 14–44 (within-gene range 5–44): ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1.

Autosomal genes at a single copy (total copy number 1): 101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
